Somatic mutation profile of tumor specimen TCGA-KK-A6E5-01A (aliquot TCGA-KK-A6E5-01A-11D-A30X-08) from TCGA case TCGA-KK-A6E5, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.4 years (23,144 days).
Specimen TCGA-KK-A6E5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5381d55e-f647-4e58-9239-9b631996e4d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A6E5-11A (Solid Tissue Normal), aliquot TCGA-KK-A6E5-11A-12D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da05bcf0-16bf-45f5-bb9a-5027e4c17463

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Frame Shift Del 4, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DENND3 | c.2581_2585del p.K861Efs*2 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs930117957; called by mutect2, pindel, varscan2
- ELOVL1 | c.215T>A p.L72H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60521896; called by muse, mutect2, varscan2
- FILIP1L | c.1310G>C p.S437T (on ENST00000354552 / NM_182909.3; = p.S197T on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV58766751; called by muse, mutect2
- FRS2 | c.1487C>G p.S496C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54724416; called by muse, mutect2, varscan2
- H2BC7 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.708); catalogued as COSV61911748; called by muse, mutect2
- KCNT1 | c.1153G>A p.V385M (on ENST00000488444; = p.V404M on NM_020822.3) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs368174673; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KERA | c.105G>T p.W35C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as COSV57130280; called by muse, mutect2, varscan2
- KMT2D | c.7246C>T p.Q2416* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as CM114115, COSV56424302; called by muse, mutect2, varscan2
- PGK2 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV59163339; called by muse, mutect2, varscan2
- SCYL3 | c.610A>C p.I204L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV100884342, COSV63045102; called by muse, mutect2, varscan2
- TOGARAM2 | c.2707A>T p.T903S | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV65420537; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1273C>T p.L425F | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV51954140, COSV51955912; called by muse, mutect2, varscan2
- UTP20 | c.3058A>G p.M1020V | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV55374545; called by muse, mutect2, varscan2
- VTA1 | c.278A>T p.Y93F | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV62658495; called by muse, mutect2
- KCNQ5 | c.1132del p.W378Gfs*20 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- MIS18BP1 | c.2252del p.L751* | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- TRPC7 | c.1976_1977del p.T659Nfs*21 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- ERG | c.948C>T p.G316= (on ENST00000398919 / NM_001243428.1; = p.G292= on NM_004449.4) | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV55729442; called by muse, mutect2
- FILIP1L | c.201C>G p.L67= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV58766286, COSV58766765; called by muse, mutect2
